Gene-level copy-number profile of tumor specimen BLGSP-71-22-00337-01A from CGCI case BLGSP-71-22-00337, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt-like lymphoma; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 7.9 years (2,877 days).
Specimen BLGSP-71-22-00337-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Retroperitoneum; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d0de74a-af35-4b0c-976a-00547ef77f93.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-22-00337-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/831eb9d1-d508-48a8-ad4f-24472444d170

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 2,970; copy number 2: 55,706; copy number 3: 156.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,851,705–106,264,715, 79 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 126. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
